Somatic mutation profile of tumor specimen C3N-02727-01 (aliquot CPT0177700006) from CPTAC case C3N-02727, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.9 years (18,210 days).
Specimen C3N-02727-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bda696d2-8fc5-4c3b-816c-5020dedb2c95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02727-71 (Blood Derived Normal), aliquot CPT0177820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8343985b-9d51-4bdd-882a-596a3966f621

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 5, Nonsense Mutation 4, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 22/271 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ABCA3 | c.3526G>A p.G1176S | Missense Mutation (SNP) | VAF 31/676 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as rs780183402; called by muse, mutect2
- ADGRA3 | c.3725C>G p.A1242G | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV51566354; called by muse, mutect2
- ARHGAP35 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68333703; called by muse, mutect2
- CFAP61 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs759937819, COSV55626654; called by muse, mutect2
- CSMD1 | c.4324C>A p.Q1442K (on ENST00000520002; = p.Q1441K on NM_033225.6) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1298544802; called by muse, mutect2
- FBN1 | c.6448C>T p.R2150C | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs76702162, CM090450, COSV57312375; ClinVar: uncertain significance; called by muse, mutect2
- GPSM1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV52517618; called by muse, mutect2
- GTPBP6 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 40/820 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755353457, COSV58205261; called by muse, mutect2
- KMT2B | c.7258A>G p.S2420G | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV55821336; called by muse, mutect2
- MAML1 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 14/292 reads (5%) | catalogued as COSV99483158; called by muse, mutect2
- NEK1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as rs780469027; called by muse, mutect2
- NUP155 | c.3359G>A p.R1120Q (on ENST00000231498 / NM_153485.3; = p.R1061Q on NM_004298.4) | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373119361; called by muse, mutect2
- USH2A | c.13023C>A p.C4341* | Nonsense Mutation (SNP) | VAF 15/228 reads (7%) | catalogued as COSV100243164; called by muse, mutect2
- ABCA8 | c.3058C>A p.L1020I | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- ADAMTS1 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- APBA2 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDB1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2
- DENND3 | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- FAM47C | c.2927T>A p.L976H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR2 | c.4267T>G p.Y1423D | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ITPR2 | c.4265C>T p.A1422V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); called by muse, mutect2
- NFAT5 | c.4448G>A p.G1483D | Missense Mutation (SNP) | VAF 9/283 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- SLC22A12 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 26/591 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- TMC5 | c.165C>A p.Y55* | Nonsense Mutation (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- ZNF524 | c.397A>T p.S133C | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ADAM2 | c.1914A>C p.S638= | Silent (SNP) | VAF 8/171 reads (5%) | called by muse, mutect2
- C1orf127 | c.1152C>G p.S384= | Silent (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- LTN1 | c.3411A>G p.E1137= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- RIMBP3 | c.3114G>A p.V1038= | Silent (SNP) | VAF 38/1246 reads (3%) | called by muse, mutect2
- STAM | c.1485C>T p.V495= | Silent (SNP) | VAF 28/580 reads (5%) | catalogued as rs1554830564; called by muse, mutect2
- UBAC2 | c.747G>A p.L249= (on ENST00000403766 / NM_001144072.2; = p.L214= on NM_177967.4) | Silent (SNP) | VAF 16/271 reads (6%) | called by muse, mutect2
- USH2A | c.14289G>A p.G4763= | Silent (SNP) | VAF 14/418 reads (3%) | catalogued as CD166027; called by muse, mutect2
- BEND6 | c.299-618A>C | Intron (SNP) | VAF 6/60 reads (10%) | catalogued as COSV66067916; called by muse, mutect2
- CPNE2 | c.927+893G>C | Intron (SNP) | VAF 8/183 reads (4%) | catalogued as rs1234986922; called by muse, mutect2
- CPSF7 | c.273+104G>T | Intron (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- MCF2L | c.169+6894C>G | Intron (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- NAV3 | c.2024-12815G>T | Intron (SNP) | VAF 10/308 reads (3%) | called by muse, mutect2
- RHBG | c.*14C>T | 3'UTR (SNP) | VAF 9/118 reads (8%) | catalogued as COSV99658975; called by muse, mutect2
- SEMA6C | c.*72G>A | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- SF3B4 | c.-4C>T | 5'UTR (SNP) | VAF 23/375 reads (6%) | catalogued as rs1553766271; called by muse, mutect2
